Somatic mutation profile of tumor specimen ALCH-B1VJ-TTP1-A (aliquot ALCH-B1VJ-TTP1-A-1-0-D-A76I-36) from ALCHEMIST case ALCH-B1VJ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 78.8 years (28,764 days).
Specimen ALCH-B1VJ-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f44905f8-320b-4fcb-b2e0-0f25e031246c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1VJ-NB1-A (Blood Derived Normal), aliquot ALCH-B1VJ-NB1-A-1-0-D-A76I-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/129fce0f-c33d-4361-9cd3-72b8e99714c5

The open-access MAF lists 695 somatic variants for this specimen: 480 protein-altering or splice-affecting, 130 silent, 85 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 400, Silent 130, Intron 41, Frame Shift Del 27, Nonsense Mutation 26, RNA 15, Splice Site 11, 5'UTR 9, Splice Region 9, 3'Flank 8, 3'UTR 7, 5'Flank 5.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB11 | c.2608G>T p.G870W | Missense Mutation (SNP) | VAF 23/40 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55589538; called by muse, varscan2
- ABCC1 | c.1083G>T p.W361C | Missense Mutation (SNP) | VAF 65/120 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV60686742; called by muse, mutect2, varscan2
- AC139530.2 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 12/92 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.838); catalogued as COSV61266560; called by muse, mutect2, varscan2
- ACBD7 | c.130G>T p.A44S | Missense Mutation (SNP) | VAF 36/118 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0.012); catalogued as rs768488252; called by muse, mutect2, varscan2
- ADAMTS2 | c.2042C>G p.S681C | Missense Mutation (SNP) | VAF 134/253 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52392890; called by muse, mutect2, varscan2
- ADCY8 | c.3683G>A p.R1228Q | Missense Mutation (SNP) | VAF 28/139 reads (20%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.885); catalogued as rs200123429, COSV53912594; called by muse, mutect2, varscan2
- AFF2 | c.898G>C p.D300H | Missense Mutation (SNP) | VAF 57/142 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as rs1372445529; called by muse, mutect2, varscan2
- AGPAT3 | c.697A>G p.R233G | Missense Mutation (SNP) | VAF 10/178 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.281); catalogued as rs1486805077; called by muse, mutect2
- AIM2 | c.715C>T p.P239S | Missense Mutation (SNP) | VAF 44/432 reads (10%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.755); catalogued as rs1371714096; called by muse, varscan2
- ALDH9A1 | c.790-1G>A p.X264_splice | Splice Site (SNP) | VAF 32/159 reads (20%) | catalogued as COSV61341544; called by muse, varscan2
- ANGPTL5 | c.259A>G p.I87V | Missense Mutation (SNP) | VAF 29/176 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as rs773693482; called by muse, mutect2, varscan2
- ANKFN1 | c.3280G>C p.D1094H (on ENST00000653862; = p.D947H on NM_001365758.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 75/160 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs758031860; called by muse, mutect2, varscan2
- ANKRD30A | c.511-1G>C p.X171_splice (on ENST00000611781; = p.X115_splice on NM_052997.2) | Splice Site (SNP) | VAF 8/53 reads (15%) | catalogued as COSV100652956, COSV64609404; called by muse, mutect2, varscan2
- BMPER | c.824C>A p.P275H | Missense Mutation (SNP) | VAF 360/833 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.635); catalogued as COSV51819841; called by muse, mutect2, varscan2
- BRINP3 | c.428G>C p.G143A | Missense Mutation (SNP) | VAF 136/220 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66535139; called by muse, mutect2, varscan2
- BSX | c.689C>A p.P230Q | Missense Mutation (SNP) | VAF 24/142 reads (17%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.006); catalogued as COSV100545258, COSV58005158; called by muse, mutect2, varscan2
- BSX | c.117C>A p.D39E | Missense Mutation (SNP) | VAF 30/189 reads (16%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as rs951758481; called by muse, mutect2, varscan2
- CACNA1G | c.2485G>A p.G829S | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs766342903, COSV104415863; called by muse, mutect2
- CADPS | c.3753G>C p.E1251D | Missense Mutation (SNP) | VAF 93/214 reads (43%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.97); catalogued as COSV51894712; called by muse, mutect2, varscan2
- CAPN8 | c.1834-6C>A | Splice Region (SNP) | VAF 55/336 reads (16%) | catalogued as rs1321218752; called by muse, mutect2, varscan2
- CASC3 | c.1208C>T p.S403F | Missense Mutation (SNP) | VAF 32/187 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV52866020; called by muse, mutect2, varscan2
- CCDC18 | c.3482A>G p.Q1161R (on ENST00000343253 / NM_001306076.1; = p.Q1162R on NM_206886.4) | Missense Mutation (SNP) | VAF 132/368 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.526); catalogued as rs1166289108; called by muse, mutect2, varscan2
- CCDC27 | c.1069G>A p.G357R | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.503); catalogued as COSV53900434; called by mutect2, varscan2
- CCIN | c.1615G>A p.V539I | Missense Mutation (SNP) | VAF 71/246 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs1385972178; called by muse, mutect2, varscan2
- CCM2L | c.1385del p.R462Pfs*46 | Frame Shift Del (DEL) | VAF 7/49 reads (14%) | catalogued as COSV52950920, COSV52952179; called by mutect2, pindel, varscan2
- CD1E | c.521G>T p.R174L | Missense Mutation (SNP) | VAF 67/636 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV63770616, COSV63772837; called by muse, mutect2, varscan2
- CFAP100 | c.77G>A p.S26N | Missense Mutation (SNP) | VAF 40/77 reads (52%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.305); catalogued as COSV61504375; called by muse, mutect2, varscan2
- CLSTN2 | c.786A>C p.Q262H | Missense Mutation (SNP) | VAF 66/130 reads (51%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.707); catalogued as rs267599628, COSV71721475; called by muse, mutect2, varscan2
- CMYA5 | c.11888C>A p.S3963Y | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT tolerated (0.45); PolyPhen benign (0.17); catalogued as rs1445900261; called by muse, mutect2, varscan2
- CNTN3 | c.1267G>T p.V423L | Missense Mutation (SNP) | VAF 111/237 reads (47%) | SIFT tolerated (0.23); PolyPhen benign (0.039); catalogued as COSV55184782, COSV99726304; called by muse, mutect2, varscan2
- CNTNAP2 | c.19G>A p.A7T | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as rs1064795189; called by muse, mutect2, varscan2
- COL25A1 | c.633C>A p.D211E | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.967); catalogued as COSV101211454; called by muse, mutect2
- COL4A1 | c.4381C>T p.P1461S | Missense Mutation (SNP) | VAF 150/348 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101011258; called by muse, mutect2, varscan2
- CWH43 | c.1356C>A p.H452Q | Missense Mutation (SNP) | VAF 39/183 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99893234; called by muse, mutect2, varscan2
- CYFIP2 | c.798G>T p.V266= | Splice Region (SNP) | VAF 69/146 reads (47%) | catalogued as rs746678833; called by muse, mutect2, varscan2
- CYP4F11 | c.100G>C p.V34L | Missense Mutation (SNP) | VAF 66/122 reads (54%) | SIFT tolerated (0.27); PolyPhen benign (0.113); catalogued as rs367904490; called by muse, mutect2, varscan2
- DEAF1 | c.69_98del p.A24_A33del | In Frame Del (DEL) | VAF 14/61 reads (23%) | catalogued as rs754135731; called by muse*, mutect2, varscan2*
- DGUOK | c.814A>C p.T272P | Missense Mutation (SNP) | VAF 96/222 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.1); catalogued as rs1159094248; called by muse, mutect2, varscan2
- DNAH14 | c.1168G>T p.A390S (on ENST00000445597; = p.A371S on NM_001145154.3) | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.539); catalogued as COSV64786430; called by muse, mutect2, varscan2
- DNAH17 | c.10711C>T p.R3571C | Missense Mutation (SNP) | VAF 49/166 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs368615279; called by muse, mutect2, varscan2
- DSC3 | c.2383del p.A795Lfs*85 | Frame Shift Del (DEL) | VAF 196/367 reads (53%) | catalogued as rs752923110; called by mutect2, varscan2
- EMID1 | c.518C>A p.P173H | Missense Mutation (SNP) | VAF 35/64 reads (55%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.591); catalogued as COSV61828482; called by muse, mutect2, varscan2
- ERCC2 | c.1660G>C p.E554Q | Missense Mutation (SNP) | VAF 78/226 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.142); catalogued as COSV67262824; called by muse, mutect2, varscan2
- ERG | c.1180G>C p.A394P (on ENST00000398919 / NM_001243428.1; = p.A370P on NM_004449.4) | Missense Mutation (SNP) | VAF 46/217 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55735568; called by muse, mutect2, varscan2
- ERRFI1 | c.1172C>A p.S391* | Nonsense Mutation (SNP) | VAF 42/195 reads (22%) | catalogued as COSV66311155; called by muse, mutect2, varscan2
- F5 | c.2515C>A p.P839T | Missense Mutation (SNP) | VAF 76/126 reads (60%) | SIFT tolerated (0.13); PolyPhen benign (0.122); catalogued as COSV63125947; called by muse, mutect2, varscan2
- FAM124A | c.835-2A>G p.X279_splice (on ENST00000322475 / NM_001242312.2; = p.X315_splice on NM_145019.4) | Splice Site (SNP) | VAF 12/32 reads (38%) | catalogued as rs775794907; called by muse, varscan2
- FAM133A | c.307C>T p.R103W | Missense Mutation (SNP) | VAF 39/97 reads (40%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.231); catalogued as rs374525042; called by muse, mutect2, varscan2
- FAM135B | c.3145A>T p.K1049* | Nonsense Mutation (SNP) | VAF 10/64 reads (16%) | catalogued as COSV99428293; called by muse, mutect2, varscan2
- FAM135B | c.1441G>T p.E481* | Nonsense Mutation (SNP) | VAF 21/115 reads (18%) | catalogued as COSV52705894, COSV52749033; called by muse, mutect2, varscan2
- FAM86B2 | c.614G>T p.G205V | Missense Mutation (SNP) | VAF 177/308 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs758719069; called by muse, mutect2, varscan2
- FAT4 | c.5159G>A p.R1720K | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.937); catalogued as COSV67894662; called by muse, varscan2
- FBH1 | c.1395C>T p.A465= (on ENST00000362091 / NM_178150.3; = p.A516= on NM_032807.4) | Splice Region (SNP) | VAF 73/267 reads (27%) | catalogued as rs768981980, COSV100758966; called by muse, mutect2, varscan2
- FCHO2 | c.1495C>T p.P499S | Missense Mutation (SNP) | VAF 68/231 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.272); catalogued as rs71636069; called by muse, mutect2, varscan2
- FGFR3 | c.1084G>T p.G362C (on ENST00000260795; = p.T311= on NM_000142.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 77/203 reads (38%) | SIFT deleterious, low confidence (0.03); catalogued as COSV99602708; called by muse, mutect2, varscan2
- FIZ1 | c.692del p.P231Rfs*18 | Frame Shift Del (DEL) | VAF 10/25 reads (40%) | catalogued as COSV99684385; called by mutect2, pindel, varscan2
- FKBP9 | c.214G>A p.D72N | Missense Mutation (SNP) | VAF 12/16 reads (75%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs758124189, COSV54232770; called by muse, mutect2, varscan2
- FPR1 | c.409C>T p.R137C | Missense Mutation (SNP) | VAF 65/124 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs139132326; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FSIP2 | c.18058del p.L6020Ffs*25 | Frame Shift Del (DEL) | VAF 15/99 reads (15%) | catalogued as COSV58087832; called by mutect2, varscan2
- FUT4 | c.797G>C p.R266P | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.034); catalogued as rs774058310; called by muse, mutect2, varscan2
- GBP5 | c.409G>C p.G137R | Missense Mutation (SNP) | VAF 78/224 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as COSV58592842; called by muse, varscan2
- GPR15 | c.987C>A p.S329R | Missense Mutation (SNP) | VAF 128/226 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.055); catalogued as COSV99423647; called by muse, varscan2
- GPR37L1 | c.1050C>A p.H350Q | Missense Mutation (SNP) | VAF 142/250 reads (57%) | SIFT tolerated (0.42); PolyPhen benign (0.028); catalogued as COSV66162884; called by muse, mutect2, varscan2
- GRAMD1B | c.178G>A p.G60S | Missense Mutation (SNP) | VAF 14/263 reads (5%) | SIFT tolerated (0.63); PolyPhen benign (0.006); catalogued as rs1218824523; called by muse, mutect2
- H2AC20 | c.292C>A p.L98M | Missense Mutation (SNP) | VAF 52/380 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); catalogued as rs782746050; called by muse, mutect2, varscan2
- HECW1 | c.2650C>A p.R884= | Splice Region (SNP) | VAF 59/121 reads (49%) | catalogued as rs927431928, COSV67820539; called by muse, mutect2, varscan2
- HMGCLL1 | c.163G>A p.V55I | Missense Mutation (SNP) | VAF 117/289 reads (40%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as rs751656245; called by muse, mutect2, varscan2
- HNF4A | c.1396C>A p.P466T | Missense Mutation (SNP) | VAF 59/181 reads (33%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1286857547; called by muse, mutect2, varscan2
- HOXD9 | c.650C>A p.A217E | Missense Mutation (SNP) | VAF 41/114 reads (36%) | SIFT tolerated (0.9); PolyPhen benign (0.001); catalogued as rs777301502, COSV99981829; called by muse, mutect2, varscan2
- IGF2BP3 | c.517G>T p.G173W | Missense Mutation (SNP) | VAF 29/183 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as rs149743260; called by muse, mutect2, varscan2
- IGFN1 | c.3368G>A p.S1123N (on ENST00000295591 / NM_001367841.1; = p.S3580N on NM_001164586.2) | Missense Mutation (SNP) | VAF 31/48 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1395666873; called by muse, mutect2, varscan2
- IGKV1-12 | c.167C>G p.A56G | Missense Mutation (SNP) | VAF 63/410 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs1232182755; called by muse, mutect2, varscan2
- IGKV1-12 | c.13G>T p.V5F | Missense Mutation (SNP) | VAF 170/1020 reads (17%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.019); catalogued as rs1350631418; called by muse, mutect2, varscan2
- IGSF9B | c.629C>A p.A210E | Missense Mutation (SNP) | VAF 40/227 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58074379; called by muse, mutect2, varscan2
- IKZF2 | c.1076A>G p.Y359C | Missense Mutation (SNP) | VAF 61/233 reads (26%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.998); catalogued as rs751327038; called by muse, mutect2, varscan2
- ITPRID2 | c.1438C>G p.P480A | Missense Mutation (SNP) | VAF 47/364 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV57473511; called by muse, mutect2, varscan2
- JMJD1C | c.3182G>A p.S1061N | Missense Mutation (SNP) | VAF 43/98 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.365); catalogued as rs776243913; called by muse, mutect2, varscan2
- JPH3 | c.802G>A p.E268K | Missense Mutation (SNP) | VAF 31/139 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.484); catalogued as rs755951557, COSV52466554; called by muse, mutect2, varscan2
- KCNJ1 | c.963G>T p.W321C | Missense Mutation (SNP) | VAF 31/141 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100131497; called by muse, mutect2, varscan2
- KCNU1 | c.2010-1G>T p.X670_splice | Splice Site (SNP) | VAF 78/171 reads (46%) | catalogued as COSV101298709; called by muse, mutect2, varscan2
- KCTD17 | c.815C>T p.P272L (on ENST00000403888 / NM_001282684.1; = p.P248L on NM_024681.3) | Missense Mutation (SNP) | VAF 51/84 reads (61%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs755400870; called by muse, mutect2, varscan2
- KEL | c.2048G>T p.R683M | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.67); catalogued as COSV100787333, COSV62333259; called by muse, mutect2, varscan2
- KHDRBS2 | c.319A>G p.M107V | Missense Mutation (SNP) | VAF 40/200 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as rs374892804; called by muse, mutect2, varscan2
- KIFAP3 | c.1763C>T p.S588F | Missense Mutation (SNP) | VAF 162/290 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV63037184; called by muse, mutect2, varscan2
- KLF10 | c.79A>T p.M27L | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs1011177502; called by muse, mutect2, varscan2
- KLHL30 | c.271G>T p.V91L | Missense Mutation (SNP) | VAF 41/142 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.38); catalogued as COSV59974695; called by muse, mutect2, varscan2
- KLHL9 | c.1525T>G p.Y509D | Missense Mutation (SNP) | VAF 71/245 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.979); catalogued as COSV100756962; called by muse, mutect2, varscan2
- KMT2D | c.14470G>A p.A4824T | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT tolerated (0.42); PolyPhen benign (0.05); catalogued as rs759709365; called by muse, mutect2, varscan2
- KRT33B | c.72del p.S25Afs*17 | Frame Shift Del (DEL) | VAF 63/159 reads (40%) | catalogued as rs752320759; called by mutect2, pindel, varscan2
- LETM2 | c.1312G>C p.D438H (on ENST00000379957 / NM_001286819.2; = p.D343H on NM_144652.3) | Missense Mutation (SNP) | VAF 113/212 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.43); catalogued as COSV52687414; called by muse, mutect2, varscan2
- LOXHD1 | c.5816A>G p.N1939S (on ENST00000642948; = p.N1877S on NM_144612.7) | Missense Mutation (SNP) | VAF 47/129 reads (36%) | SIFT tolerated (0.94); PolyPhen benign (0.031); catalogued as rs1212807729; called by muse, mutect2, varscan2
- LRP1B | c.9434A>T p.Y3145F | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV67193350; called by muse, mutect2, varscan2
- LZTR1 | c.1768C>T p.Q590* | Nonsense Mutation (SNP) | VAF 52/124 reads (42%) | catalogued as rs754685052; called by muse, mutect2, varscan2
- MAP1A | c.7907C>A p.P2636H | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as rs568062409; called by muse, mutect2, varscan2
- MAP1B | c.5122G>A p.E1708K | Missense Mutation (SNP) | VAF 49/215 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs199691201; called by muse, mutect2, varscan2
- MAPK4 | c.1633C>G p.R545G | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.034); catalogued as COSV68544139; called by muse, mutect2, varscan2
- MEX3D | c.1120G>A p.A374T | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.689); catalogued as rs1270769445; called by muse, mutect2, varscan2
- MROH2B | c.511G>T p.D171Y | Missense Mutation (SNP) | VAF 59/136 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV101270740, COSV68188914; called by muse, mutect2, varscan2
- MTUS2 | c.3117G>T p.K1039N | Missense Mutation (SNP) | VAF 60/105 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV70923508; called by muse, mutect2, varscan2
- MYO16 | c.4447C>T p.P1483S | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV62758985; called by muse, mutect2, varscan2
- NKD2 | c.922C>T p.P308S | Missense Mutation (SNP) | VAF 34/117 reads (29%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.605); catalogued as rs1463666366; called by muse, mutect2, varscan2
- NLGN4X | c.400A>G p.T134A | Missense Mutation (SNP) | VAF 102/216 reads (47%) | SIFT tolerated (0.65); PolyPhen benign (0.009); catalogued as rs774379413; called by muse, mutect2, varscan2
- NLRP13 | c.158C>T p.P53L | Missense Mutation (SNP) | VAF 55/155 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs145312636; called by muse, mutect2, varscan2
- NPNT | c.149G>T p.R50L | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs747884992; called by muse, mutect2, varscan2
- NPTX2 | c.77G>A p.R26H | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as rs1297775623; called by muse, mutect2, varscan2
- NTNG1 | c.125G>T p.G42V | Missense Mutation (SNP) | VAF 143/428 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV53978810; called by muse, mutect2, varscan2
- OGFRL1 | c.442T>A p.Y148N | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1219057853; called by muse, mutect2, varscan2
- OR10G8 | c.716C>A p.T239N | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV101461762; called by muse, mutect2, varscan2
- OR1S1 | c.908A>G p.Y303C | Missense Mutation (SNP) | VAF 34/164 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770476205; called by muse, mutect2, varscan2
- OR2A12 | c.545C>A p.S182Y | Missense Mutation (SNP) | VAF 96/402 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV68821502; called by muse, mutect2, varscan2
- OR2H1 | c.749A>G p.Y250C | Missense Mutation (SNP) | VAF 71/312 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65810950; called by muse, mutect2, varscan2
- OR2L5 | c.733A>T p.T245S | Missense Mutation (SNP) | VAF 118/169 reads (70%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV62364714; called by muse, mutect2, varscan2
- OR2T3 | c.296C>A p.P99Q | Missense Mutation (SNP) | VAF 241/715 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0.277); catalogued as COSV100613033, COSV62081664; called by muse, mutect2, varscan2
- OR2T34 | c.296C>A p.P99Q | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.277); catalogued as COSV60899841; called by muse, mutect2
- OR2W3 | c.725G>T p.G242V | Missense Mutation (SNP) | VAF 96/392 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs1323055342; called by muse, varscan2
- OR4C11 | c.150C>A p.S50R | Missense Mutation (SNP) | VAF 41/133 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.448); catalogued as COSV56353203; called by muse, mutect2, varscan2
- OR4M1 | c.580C>T p.P194S | Missense Mutation (SNP) | VAF 84/566 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs749051838, COSV60063647; called by muse, mutect2, varscan2
- OR51T1 | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 96/182 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.761); catalogued as COSV100434241, COSV59024827; called by muse, mutect2, varscan2
- OR5D14 | c.635C>G p.T212R | Missense Mutation (SNP) | VAF 48/302 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV100162322; called by muse, mutect2, varscan2
- OR6K2 | c.575G>C p.R192P | Missense Mutation (SNP) | VAF 181/412 reads (44%) | SIFT tolerated (0.34); PolyPhen benign (0.362); catalogued as COSV62743302; called by muse, mutect2, varscan2
- OR8K3 | c.722G>C p.G241A | Missense Mutation (SNP) | VAF 12/242 reads (5%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.558); catalogued as rs766683127, COSV57133123; called by muse, mutect2
- OVCH1 | c.2648G>T p.S883I | Missense Mutation (SNP) | VAF 67/360 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.093); catalogued as COSV58959597; called by muse, mutect2, varscan2
- PASK | c.2332G>C p.D778H | Missense Mutation (SNP) | VAF 82/268 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as rs769254338; called by muse, mutect2, varscan2
- PCSK5 | c.4096C>A p.R1366S | Missense Mutation (SNP) | VAF 98/256 reads (38%) | SIFT tolerated (0.38); PolyPhen benign (0.009); catalogued as COSV70447767; called by muse, mutect2, varscan2
- PDGFRA | c.1729C>A p.P577T | Missense Mutation (SNP) | VAF 166/392 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV57264474; called by muse, varscan2
- PDZK1 | c.38C>A p.S13Y | Missense Mutation (SNP) | VAF 54/280 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV100777375; called by muse, mutect2, varscan2
- PGAP4 | c.1163T>A p.I388N | Missense Mutation (SNP) | VAF 21/148 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV66387910, COSV66388049; called by muse, mutect2
- PIK3R2 | c.977A>C p.Q326P | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT tolerated (0.08); PolyPhen benign (0.204); catalogued as rs1195469255; called by muse, mutect2, varscan2
- PNLIPRP1 | c.365G>A p.C122Y | Missense Mutation (SNP) | VAF 98/190 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62612399; called by muse, mutect2, varscan2
- POTEE | c.2518C>A p.P840T | Missense Mutation (SNP) | VAF 51/427 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.028); catalogued as COSV100387846, COSV58230641; called by muse, mutect2, varscan2
- PSG6 | c.1178G>C p.C393S | Missense Mutation (SNP) | VAF 153/324 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1387137710; called by muse, mutect2, varscan2
- PTPRD | c.553G>A p.G185S | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.393); catalogued as COSV61979006; called by muse, mutect2, varscan2
- PTPRF | c.3524G>C p.R1175P | Missense Mutation (SNP) | VAF 24/170 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV100741000, COSV63446499; called by mutect2, varscan2
- RASA1 | c.2708G>A p.R903Q | Missense Mutation (SNP) | VAF 56/178 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV57191137; called by muse, mutect2, varscan2
- SATB2 | c.988C>A p.Q330K | Missense Mutation (SNP) | VAF 30/208 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.633); catalogued as COSV53484250; called by muse, mutect2, varscan2
- SCN4A | c.5293G>T p.A1765S | Missense Mutation (SNP) | VAF 46/68 reads (68%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.159); catalogued as COSV71127502; called by muse, mutect2, varscan2
- SCN5A | c.3695G>A p.R1232Q (on ENST00000333535 / NM_198056.3; = p.R1231Q on NM_000335.5) | Missense Mutation (SNP) | VAF 36/154 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as rs199473206, CM100694, COSV61138843; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCN8A | c.3648C>T p.A1216= | Splice Region (SNP) | VAF 23/95 reads (24%) | catalogued as rs550365847; called by muse, mutect2, varscan2
- SELE | c.518A>T p.K173M | Missense Mutation (SNP) | VAF 93/150 reads (62%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.797); catalogued as COSV100324462; called by muse, mutect2, varscan2
- SEMA3A | c.1108C>A p.Q370K | Missense Mutation (SNP) | VAF 96/207 reads (46%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.55); catalogued as COSV99548470; called by muse, mutect2, varscan2
- SEMA3D | c.580G>A p.V194I | Missense Mutation (SNP) | VAF 93/224 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as COSV52408874; called by muse, mutect2, varscan2
- SEPTIN14 | c.170G>A p.C57Y | Missense Mutation (SNP) | VAF 81/162 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101193218, COSV66426452; called by muse, mutect2, varscan2
- SFTPB | c.709G>T p.V237L | Missense Mutation (SNP) | VAF 50/165 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.16); catalogued as COSV60894694; called by muse, mutect2, varscan2
- SHCBP1L | c.1835G>A p.R612K | Missense Mutation (SNP) | VAF 64/317 reads (20%) | SIFT tolerated (0.68); PolyPhen benign (0.027); catalogued as COSV62354825, COSV62357083; called by muse, mutect2, varscan2
- SIK3 | c.1094C>T p.A365V (on ENST00000445177 / NM_001366686.2; = p.A371V on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 49/309 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs865894323; called by muse, mutect2, varscan2
- SLC17A8 | c.1382G>T p.G461V | Missense Mutation (SNP) | VAF 192/388 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs147189857; called by muse, mutect2, varscan2
- SLC22A24 | c.1096G>A p.G366S | Missense Mutation (SNP) | VAF 34/206 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV104434680; called by muse, mutect2, varscan2
- SLITRK3 | c.1808G>T p.R603L | Missense Mutation (SNP) | VAF 46/96 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.68); catalogued as COSV99579206, COSV99580353; called by muse, mutect2, varscan2
- SNTG1 | c.163G>T p.E55* | Nonsense Mutation (SNP) | VAF 79/221 reads (36%) | catalogued as COSV52451225; called by muse, mutect2, varscan2
- SNX15 | c.427C>T p.P143S | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.255); catalogued as rs759398023; called by muse, mutect2, varscan2
- STARD3 | c.811G>T p.V271L | Missense Mutation (SNP) | VAF 118/225 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.739); catalogued as COSV59224314; called by muse, mutect2, varscan2
- STK10 | c.910C>T p.R304W | Missense Mutation (SNP) | VAF 103/213 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs866300383; called by muse, mutect2, varscan2
- SYTL5 | c.230G>A p.R77Q | Missense Mutation (SNP) | VAF 71/171 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs780574469, COSV52905721; called by muse, mutect2, varscan2
- TAPBPL | c.1078G>A p.A360T | Missense Mutation (SNP) | VAF 142/292 reads (49%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.597); catalogued as rs1483036676, COSV99869007; called by muse, mutect2, varscan2
- TFAP4 | c.874C>A p.Q292K | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV52596827, COSV52597813; called by muse, mutect2, varscan2
- TG | c.6530G>T p.R2177L | Missense Mutation (SNP) | VAF 70/367 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.676); catalogued as rs761804509; called by muse, mutect2, varscan2
- TM9SF4 | c.1915G>T p.V639L | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.539); catalogued as COSV54107472; called by muse, mutect2, varscan2
- TMEM132C | c.1686G>T p.E562D | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT tolerated (0.84); PolyPhen benign (0.05); catalogued as COSV59430597; called by muse, mutect2, varscan2
- TMEM132C | c.3253G>T p.V1085L | Missense Mutation (SNP) | VAF 47/91 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); catalogued as rs1192753122; called by muse, mutect2, varscan2
- TMEM229B | c.196C>T p.R66W | Missense Mutation (SNP) | VAF 6/116 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.395); catalogued as rs926386994; called by muse, mutect2
- TMEM248 | c.893G>T p.R298L | Missense Mutation (SNP) | VAF 36/150 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV58576849; called by muse, mutect2, varscan2
- TMPRSS7 | c.377G>T p.R126L (on ENST00000452346; = p.R14L on NM_001042575.2) | Missense Mutation (SNP) | VAF 92/218 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.462); catalogued as COSV69981079; called by muse, mutect2, varscan2
- TNK1 | c.950T>A p.F317Y | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV61171120; called by muse, mutect2, varscan2
- TNXB | c.9724G>A p.V3242M (on ENST00000647633; = p.V2995M on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 124/196 reads (63%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.972); catalogued as rs1428504069; called by muse, mutect2, varscan2
- TRIM64C | c.1088C>A p.T363K | Missense Mutation (SNP) | VAF 98/212 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1055681859; called by muse, mutect2, varscan2
- TTLL4 | c.3483G>T p.E1161D | Missense Mutation (SNP) | VAF 193/614 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.081); catalogued as rs1324637288; called by muse, mutect2, varscan2
- UGT1A8 | c.573del p.R192Efs*4 | Frame Shift Del (DEL) | VAF 66/284 reads (23%) | catalogued as COSV65085055; called by mutect2, pindel, varscan2
- USH1C | c.1285-3C>T | Splice Region (SNP) | VAF 26/45 reads (58%) | catalogued as rs761895199; called by muse, mutect2, varscan2
- VXN | c.223C>T p.R75W | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as rs774421011; called by muse, mutect2, varscan2
- XIRP2 | c.6716G>A p.G2239E (on ENST00000628543; = p.G2414E on NM_152381.6) | Missense Mutation (SNP) | VAF 22/177 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.006); catalogued as COSV54685031; called by muse, varscan2
- ZC3H18 | c.1841C>T p.P614L | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs756156137; called by muse, mutect2, varscan2
- ZFHX4 | c.9037G>C p.G3013R | Missense Mutation (SNP) | VAF 33/173 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as COSV50493419, COSV99254152; called by muse, mutect2, varscan2
- ZMYM6 | c.946+2T>A p.X316_splice | Splice Site (SNP) | VAF 16/54 reads (30%) | catalogued as rs1214609575; called by muse, mutect2, varscan2
- ZNF121 | c.267A>C p.E89D | Missense Mutation (SNP) | VAF 122/248 reads (49%) | SIFT tolerated (0.42); PolyPhen benign (0.046); catalogued as rs772716113; called by muse, mutect2, varscan2
- ZNF99 | c.2078G>T p.R693M | Missense Mutation (SNP) | VAF 60/240 reads (25%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.821); catalogued as rs1289459231, COSV68055960; called by muse, varscan2
- ABCB1 | c.657G>C p.L219F | Missense Mutation (SNP) | VAF 94/487 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- ACTL6B | c.930C>A p.N310K | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.386); called by muse, mutect2, varscan2
- ADAM30 | c.1090G>T p.G364C | Missense Mutation (SNP) | VAF 27/139 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.448); called by muse, mutect2, varscan2
- ADARB2 | c.902G>A p.R301Q | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated (0.48); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- ADCY1 | c.971T>A p.L324Q | Missense Mutation (SNP) | VAF 61/473 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADGRF2 | c.877A>T p.M293L (on ENST00000296862 / NM_001368115.2; = p.M225L on NM_153839.7) | Missense Mutation (SNP) | VAF 49/91 reads (54%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- AEBP1 | c.333G>T p.E111D | Missense Mutation (SNP) | VAF 109/355 reads (31%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- AHI1 | c.1488G>T p.L496F | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- AHNAK2 | c.3258G>C p.M1086I | Missense Mutation (SNP) | VAF 64/153 reads (42%) | SIFT tolerated (0.24); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- ANK1 | c.1242G>T p.M414I | Missense Mutation (SNP) | VAF 94/442 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- ANK2 | c.2815G>A p.E939K | Missense Mutation (SNP) | VAF 104/489 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- ANO3 | c.2149C>T p.Q717* | Nonsense Mutation (SNP) | VAF 54/117 reads (46%) | called by muse, mutect2, varscan2
- AP000721.1 | c.230C>T p.A77V | Missense Mutation (SNP) | VAF 44/88 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.691); called by muse, varscan2
- APOB | c.978G>T p.L326F | Missense Mutation (SNP) | VAF 61/260 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- ARHGAP24 | c.1977G>T p.K659N (on ENST00000395184 / NM_001025616.3; = p.K566N on NM_031305.3) | Missense Mutation (SNP) | VAF 78/195 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ARHGEF11 | c.3779del p.G1260Vfs*64 | Frame Shift Del (DEL) | VAF 79/227 reads (35%) | called by mutect2, pindel, varscan2
- ARL14EPL | c.47C>A p.T16K | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (0.45); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ARMC3 | c.816G>T p.Q272H | Missense Mutation (SNP) | VAF 34/141 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.429); called by muse, varscan2
- ARMC8 | c.4G>T p.A2S | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- ARNT | c.886G>T p.V296L | Missense Mutation (SNP) | VAF 44/297 reads (15%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARV1 | c.790G>T p.A264S | Missense Mutation (SNP) | VAF 109/165 reads (66%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ARVCF | c.1655A>T p.H552L | Missense Mutation (SNP) | VAF 70/133 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- ATAD2 | c.1513T>C p.W505R | Missense Mutation (SNP) | VAF 51/183 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATG16L1 | c.1639A>T p.S547C (on ENST00000392017 / NM_030803.7; = p.S528C on NM_017974.4) | Missense Mutation (SNP) | VAF 96/294 reads (33%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.705); called by muse, varscan2
- ATP6V0D2 | c.47T>A p.L16Q | Missense Mutation (SNP) | VAF 46/266 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATP8B4 | c.3310C>T p.Q1104* | Nonsense Mutation (SNP) | VAF 13/46 reads (28%) | called by muse, mutect2, varscan2
- AXIN2 | c.628A>T p.M210L | Missense Mutation (SNP) | VAF 243/362 reads (67%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2, varscan2
- B3GALT5 | c.433T>A p.F145I | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.813); called by muse, mutect2, varscan2
- B3GNT6 | c.169G>A p.A57T | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BAAT | c.146A>G p.H49R | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.72); PolyPhen benign (0.359); called by muse, mutect2, varscan2
- BAZ2B | c.5645G>T p.R1882L | Missense Mutation (SNP) | VAF 148/572 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- BIN1 | c.1603G>A p.D535N (on ENST00000316724 / NM_001320642.1; = p.D396N on NM_004305.4) | Missense Mutation (SNP) | VAF 76/467 reads (16%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BSX | c.118C>A p.H40N | Missense Mutation (SNP) | VAF 30/190 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- BTK | c.1980A>T p.*660Cext*4 | Nonstop Mutation (SNP) | VAF 46/81 reads (57%) | called by muse, mutect2, varscan2
- BTNL3 | c.787+2T>A p.X263_splice | Splice Site (SNP) | VAF 140/236 reads (59%) | called by muse, varscan2
- C11orf21 | c.109A>G p.R37G (on ENST00000381153 / NM_001329958.2; = p.R83G on NM_001142946.3) | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- C12orf75 | c.50C>A p.P17H | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- C19orf38 | c.410C>A p.A137D | Missense Mutation (SNP) | VAF 57/136 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.387); called by muse, mutect2, varscan2
- C1orf94 | c.830G>T p.G277V (on ENST00000488417 / NM_001134734.2; = p.G87V on NM_032884.5) | Missense Mutation (SNP) | VAF 61/246 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- C1orf94 | c.1582C>A p.P528T (on ENST00000488417 / NM_001134734.2; = p.P338T on NM_032884.5) | Missense Mutation (SNP) | VAF 30/123 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- C4orf47 | c.286A>T p.K96* | Nonsense Mutation (SNP) | VAF 72/148 reads (49%) | called by muse, mutect2, varscan2
- C6orf118 | c.484G>A p.G162S | Missense Mutation (SNP) | VAF 68/126 reads (54%) | SIFT tolerated (0.88); PolyPhen benign (0.176); called by muse, mutect2, varscan2
- C7orf25 | c.159A>T p.E53D | Missense Mutation (SNP) | VAF 121/298 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- CA9 | c.403+1G>T p.X135_splice | Splice Site (SNP) | VAF 11/63 reads (17%) | called by muse, mutect2, varscan2
- CALHM1 | c.496G>T p.D166Y | Missense Mutation (SNP) | VAF 91/187 reads (49%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.716); called by muse, mutect2, varscan2
- CARD11 | c.1325G>T p.S442I | Missense Mutation (SNP) | VAF 69/238 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CBLIF | c.896C>A p.P299H | Missense Mutation (SNP) | VAF 228/607 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- CCIN | c.1614T>A p.D538E | Missense Mutation (SNP) | VAF 69/247 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- CCM2L | c.175G>T p.D59Y | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CD248 | c.1587G>T p.Q529H | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- CD84 | c.522G>T p.E174D | Missense Mutation (SNP) | VAF 95/441 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- CDCP2 | c.1162G>T p.A388S | Missense Mutation (SNP) | VAF 55/179 reads (31%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CDH18 | c.914A>G p.Y305C | Missense Mutation (SNP) | VAF 80/166 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CEP128 | c.2331dup p.L778Tfs*22 | Frame Shift Ins (INS) | VAF 55/224 reads (25%) | called by mutect2, pindel, varscan2
- CERS3 | c.496T>C p.W166R | Missense Mutation (SNP) | VAF 70/142 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CHAC1 | c.204C>A p.D68E | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- CHRM2 | c.982G>T p.G328C | Missense Mutation (SNP) | VAF 44/100 reads (44%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- CHST6 | c.1056del p.L353Cfs*28 | Frame Shift Del (DEL) | VAF 137/294 reads (47%) | called by mutect2, pindel, varscan2
- CIAO1 | c.977G>T p.G326V | Missense Mutation (SNP) | VAF 74/236 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CIAO3 | c.952G>A p.G318S | Missense Mutation (SNP) | VAF 31/103 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CLCN3 | c.2049G>T p.M683I | Missense Mutation (SNP) | VAF 43/78 reads (55%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- CNTN4 | c.1006G>T p.E336* | Nonsense Mutation (SNP) | VAF 73/140 reads (52%) | called by muse, mutect2, varscan2
- COL11A1 | c.4480G>T p.A1494S | Missense Mutation (SNP) | VAF 94/488 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- COL14A1 | c.4905C>G p.Y1635* | Nonsense Mutation (SNP) | VAF 36/240 reads (15%) | called by muse, mutect2, varscan2
- COL27A1 | c.560G>T p.R187M | Missense Mutation (SNP) | VAF 63/129 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- COL4A5 | c.908A>T p.D303V | Missense Mutation (SNP) | VAF 73/153 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL6A6 | c.361G>T p.A121S | Missense Mutation (SNP) | VAF 80/164 reads (49%) | SIFT tolerated (0.28); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- CPT1C | c.724C>A p.L242M | Missense Mutation (SNP) | VAF 65/160 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- CRMP1 | c.1437C>A p.Y479* | Nonsense Mutation (SNP) | VAF 49/119 reads (41%) | called by muse, mutect2, varscan2
- CSMD1 | c.8645T>C p.V2882A (on ENST00000520002; = p.V2881A on NM_033225.6) | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- CSMD1 | c.3462A>T p.E1154D (on ENST00000520002; = p.E1153D on NM_033225.6) | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CUL9 | c.3220G>T p.V1074L | Missense Mutation (SNP) | VAF 98/199 reads (49%) | SIFT tolerated (0.05); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CYP11B2 | c.985G>C p.E329Q | Missense Mutation (SNP) | VAF 125/356 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CYP4X1 | c.1396del p.V466* | Frame Shift Del (DEL) | VAF 54/211 reads (26%) | called by mutect2, pindel, varscan2
- CYSLTR2 | c.793A>T p.T265S | Missense Mutation (SNP) | VAF 77/193 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- DBX1 | c.167G>A p.R56H | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- DENND4A | c.3163G>C p.D1055H | Missense Mutation (SNP) | VAF 57/105 reads (54%) | SIFT tolerated (0.13); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- DHX35 | c.217G>T p.V73L | Missense Mutation (SNP) | VAF 46/115 reads (40%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- DISP3 | c.1553T>A p.L518Q | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DMAP1 | c.629del p.G210Afs*62 | Frame Shift Del (DEL) | VAF 13/74 reads (18%) | called by mutect2, pindel, varscan2
- DNAH10 | c.1264C>A p.L422M (on ENST00000409039; = p.L361M on NM_207437.3) | Missense Mutation (SNP) | VAF 31/45 reads (69%) | SIFT tolerated (0.06); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- DNAH11 | c.9932G>T p.C3311F | Missense Mutation (SNP) | VAF 52/233 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAI4 | c.1119G>T p.M373I | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT tolerated (0.45); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DYRK1B | c.1105G>T p.G369C | Missense Mutation (SNP) | VAF 33/61 reads (54%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.704); called by muse, mutect2, varscan2
- DYTN | c.1135C>A p.L379I | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- EEF2 | c.897+1G>T p.X299_splice | Splice Site (SNP) | VAF 25/53 reads (47%) | called by muse, mutect2, varscan2
- EML5 | c.4386_4389del p.I1463* (on ENST00000380664; = p.I1471* on NM_183387.3) | Frame Shift Del (DEL) | VAF 31/147 reads (21%) | called by pindel, varscan2
- EPHB1 | c.1174T>C p.S392P | Missense Mutation (SNP) | VAF 43/170 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.119); called by muse, varscan2
- ESPN | c.1880G>T p.G627V | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- EVC2 | c.883C>T p.H295Y | Missense Mutation (SNP) | VAF 156/565 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- F5 | c.2516C>A p.P839H | Missense Mutation (SNP) | VAF 73/124 reads (59%) | SIFT tolerated (0.12); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- FAM193A | c.86A>G p.Q29R | Missense Mutation (SNP) | VAF 33/285 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FAM3B | c.20-2A>T p.X7_splice | Splice Site (SNP) | VAF 211/443 reads (48%) | called by muse, mutect2, varscan2
- FAM78B | c.216G>T p.Q72H | Missense Mutation (SNP) | VAF 149/277 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- FAT3 | c.5661_5662del p.F1888* | Frame Shift Del (DEL) | VAF 27/123 reads (22%) | called by pindel, varscan2
- FAT4 | c.2959C>T p.H987Y | Missense Mutation (SNP) | VAF 22/175 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- FBLIM1 | c.475C>T p.L159F | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- FCAR | c.252G>T p.E84D | Missense Mutation (SNP) | VAF 58/338 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- FCGR2B | c.166C>G p.P56A | Missense Mutation (SNP) | VAF 168/786 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FCRLA | c.694T>A p.F232I (on ENST00000367959; = p.F209I on NM_032738.4) | Missense Mutation (SNP) | VAF 139/385 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FEM1A | c.1930G>T p.A644S | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FGF2 | c.34G>A p.V12M | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.162); called by muse, varscan2
- FGF6 | c.292C>A p.L98I | Missense Mutation (SNP) | VAF 66/164 reads (40%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.49); called by muse, mutect2, varscan2
- FNDC1 | c.2561C>T p.P854L | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- FNDC1 | c.3359G>T p.G1120V | Missense Mutation (SNP) | VAF 45/76 reads (59%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- FOXD1 | c.178G>T p.A60S | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.676); called by muse, mutect2, varscan2
- FOXI2 | c.510A>T p.P170= | Splice Region (SNP) | VAF 86/148 reads (58%) | called by muse, mutect2, varscan2
- FRAS1 | c.5665+2T>C p.X1889_splice | Splice Site (SNP) | VAF 49/257 reads (19%) | called by muse, mutect2, varscan2
- FRMPD4 | c.1704_1705delinsT p.Q569Rfs*2 | Frame Shift Del (DEL) | VAF 29/81 reads (36%) | called by pindel, varscan2*
- FSIP2 | c.18062del p.F6021Sfs*24 | Frame Shift Del (DEL) | VAF 11/96 reads (11%) | called by mutect2*, pindel, varscan2*
- FURIN | c.257G>T p.R86L | Missense Mutation (SNP) | VAF 70/136 reads (51%) | SIFT tolerated (0.21); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- FUT7 | c.16C>A p.H6N | Missense Mutation (SNP) | VAF 68/125 reads (54%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- FYB1 | c.524G>C p.G175A | Missense Mutation (SNP) | VAF 136/332 reads (41%) | SIFT tolerated (0.4); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- GALK2 | c.911T>C p.L304P | Missense Mutation (SNP) | VAF 129/281 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GK2 | c.89C>A p.S30* | Nonsense Mutation (SNP) | VAF 67/163 reads (41%) | called by muse, mutect2, varscan2
- GPR55 | c.900G>T p.R300S | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT tolerated (0.74); PolyPhen benign (0); called by muse, mutect2, varscan2
- GPR89A | c.341G>C p.C114S | Missense Mutation (SNP) | VAF 20/160 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0); called by mutect2, varscan2
- GRIK4 | c.1168G>T p.G390C | Missense Mutation (SNP) | VAF 30/136 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- H4C7 | c.188T>A p.L63Q | Missense Mutation (SNP) | VAF 65/112 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- HAO1 | c.318G>C p.M106I | Missense Mutation (SNP) | VAF 48/87 reads (55%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- HAPLN1 | c.215C>A p.S72* | Nonsense Mutation (SNP) | VAF 40/123 reads (33%) | called by muse, mutect2, varscan2
- HOXD4 | c.158C>G p.P53R | Missense Mutation (SNP) | VAF 33/161 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- HRH3 | c.1034C>G p.T345S | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- IGHV3-53 | c.236C>A p.A79E | Missense Mutation (SNP) | VAF 112/416 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- IGSF1 | c.1054C>A p.L352I | Missense Mutation (SNP) | VAF 49/112 reads (44%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- IGSF21 | c.71-1G>A p.X24_splice | Splice Site (SNP) | VAF 28/106 reads (26%) | called by muse, mutect2, varscan2
- IL16 | c.132del p.F45Lfs*33 | Frame Shift Del (DEL) | VAF 43/84 reads (51%) | called by mutect2, pindel*, varscan2
- IMPG1 | c.2279_2286delinsA p.T760Kfs*12 | Frame Shift Del (DEL) | VAF 39/148 reads (26%) | called by pindel, varscan2*
- INTS1 | c.4604G>T p.S1535I | Missense Mutation (SNP) | VAF 125/239 reads (52%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- IQCA1 | c.1427G>T p.G476V | Missense Mutation (SNP) | VAF 64/285 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IRF2BPL | c.439G>T p.E147* | Nonsense Mutation (SNP) | VAF 62/108 reads (57%) | called by muse, varscan2
- ITGA2 | c.2822C>A p.T941K | Missense Mutation (SNP) | VAF 137/346 reads (40%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.667); called by muse, mutect2, varscan2
- ITGA4 | c.982C>A p.P328T | Missense Mutation (SNP) | VAF 110/427 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ITIH2 | c.544C>T p.H182Y | Missense Mutation (SNP) | VAF 58/192 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IZUMO1R | c.587G>T p.S196I (on ENST00000440961; = p.S203I on NM_001199206.3) | Missense Mutation (SNP) | VAF 72/431 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- KALRN | c.4929G>C p.K1643N | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KANK3 | c.1015T>A p.W339R | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); called by muse, mutect2, varscan2
- KIF19 | c.1283G>T p.S428I | Missense Mutation (SNP) | VAF 59/220 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- KIF26B | c.4882A>C p.N1628H | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIF7 | c.1509C>A p.N503K | Missense Mutation (SNP) | VAF 96/189 reads (51%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KNDC1 | c.64T>A p.Y22N | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- KRT76 | c.1078C>A p.Q360K | Missense Mutation (SNP) | VAF 36/65 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- LAMA2 | c.5690C>G p.A1897G | Missense Mutation (SNP) | VAF 123/293 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- LHX1 | c.1067G>T p.S356I | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LHX3 | c.149A>C p.H50P (on ENST00000371748 / NM_178138.6; = p.H55P on NM_014564.5) | Missense Mutation (SNP) | VAF 59/263 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.321); called by muse, mutect2, varscan2
- LRP2 | c.344G>T p.C115F | Missense Mutation (SNP) | VAF 140/511 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRRTM3 | c.1158G>T p.R386S | Missense Mutation (SNP) | VAF 46/102 reads (45%) | SIFT tolerated (0.84); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MC3R | c.854T>G p.L285R | Missense Mutation (SNP) | VAF 63/188 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- MEP1B | c.1214G>C p.R405P | Missense Mutation (SNP) | VAF 201/340 reads (59%) | SIFT deleterious (0.02); PolyPhen benign (0.414); called by muse, mutect2, varscan2
- MFSD5 | c.406C>G p.L136V | Missense Mutation (SNP) | VAF 93/181 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- MICAL3 | c.5152G>T p.G1718C | Missense Mutation (SNP) | VAF 77/143 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.498); called by muse, mutect2, varscan2
- MIIP | c.576del p.S193Afs*91 | Frame Shift Del (DEL) | VAF 34/159 reads (21%) | called by mutect2, pindel, varscan2
- MLPH | c.1279G>C p.A427P | Missense Mutation (SNP) | VAF 119/389 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- MMP2 | c.1022G>T p.G341V | Missense Mutation (SNP) | VAF 87/389 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MPO | c.1328A>T p.Y443F | Missense Mutation (SNP) | VAF 122/235 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- MSANTD4 | c.670G>T p.E224* | Nonsense Mutation (SNP) | VAF 24/110 reads (22%) | called by muse, varscan2
- MTHFR | c.931G>T p.A311S | Missense Mutation (SNP) | VAF 54/187 reads (29%) | SIFT tolerated (0.72); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- MTREX | c.41dup p.D16Rfs*34 | Frame Shift Ins (INS) | VAF 80/211 reads (38%) | called by mutect2, pindel, varscan2
- MUC16 | c.34343C>G p.P11448R | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- MUC17 | c.5162T>C p.V1721A | Missense Mutation (SNP) | VAF 33/101 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- MUC17 | c.7636G>A p.V2546M | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- MXRA5 | c.2497C>A p.Q833K | Missense Mutation (SNP) | VAF 32/65 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- MYH1 | c.3088A>G p.K1030E | Missense Mutation (SNP) | VAF 47/253 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- MYO3B | c.304C>A p.L102M | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NES | c.3794A>C p.E1265A | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- NEUROD4 | c.224dup p.K76Efs*8 | Frame Shift Ins (INS) | VAF 68/342 reads (20%) | called by mutect2, pindel, varscan2
- NEUROD6 | c.535G>T p.G179C | Missense Mutation (SNP) | VAF 97/429 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NF1 | c.4724G>T p.R1575M (on ENST00000358273 / NM_001042492.3; = p.R1554M on NM_000267.3) | Missense Mutation (SNP) | VAF 66/165 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- NLRC4 | c.1700C>A p.S567Y | Missense Mutation (SNP) | VAF 71/133 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- NOTUM | c.1184G>T p.S395I | Missense Mutation (SNP) | VAF 41/150 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.303); called by muse, mutect2, varscan2
- NR2E1 | c.64del p.R22Afs*54 | Frame Shift Del (DEL) | VAF 93/218 reads (43%) | called by mutect2, pindel, varscan2
- NSD2 | c.1675-7A>G | Splice Region (SNP) | VAF 48/166 reads (29%) | called by mutect2, varscan2
- NUDCD3 | c.621G>T p.K207N | Missense Mutation (SNP) | VAF 49/226 reads (22%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.446); called by muse, varscan2
- NUP107 | c.940G>T p.G314* | Nonsense Mutation (SNP) | VAF 41/216 reads (19%) | called by muse, mutect2, varscan2
- OCSTAMP | c.542G>T p.G181V | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- OGFR | c.1639G>T p.A547S | Missense Mutation (SNP) | VAF 61/355 reads (17%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- OR10Q1 | c.479C>A p.S160Y | Missense Mutation (SNP) | VAF 110/277 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- OR10Q1 | c.368C>G p.A123G | Missense Mutation (SNP) | VAF 46/123 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OR10T2 | c.684G>T p.K228N | Missense Mutation (SNP) | VAF 25/157 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- OR13C2 | c.706A>C p.K236Q | Missense Mutation (SNP) | VAF 24/174 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR2C3 | c.839C>A p.T280N | Missense Mutation (SNP) | VAF 182/465 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.007); called by muse, varscan2
- OR2L2 | c.351G>T p.M117I | Missense Mutation (SNP) | VAF 265/396 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- OR2L3 | c.436G>T p.G146W | Missense Mutation (SNP) | VAF 41/340 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR2M4 | c.777C>A p.Y259* | Nonsense Mutation (SNP) | VAF 214/304 reads (70%) | called by muse, mutect2, varscan2
- OR2T6 | c.633C>A p.F211L | Missense Mutation (SNP) | VAF 31/350 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.034); called by muse, mutect2
- OR4D10 | c.815C>T p.S272F | Missense Mutation (SNP) | VAF 22/217 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- OR4D5 | c.326G>T p.G109V | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- OR52A1 | c.791C>A p.T264K | Missense Mutation (SNP) | VAF 70/194 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- OR5B3 | c.449G>T p.G150V | Missense Mutation (SNP) | VAF 36/154 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- OR6B3 | c.392G>A p.R131H | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT tolerated (0.53); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OR7G2 | c.513G>C p.L171F | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, varscan2
- OR8D4 | c.764T>C p.L255P | Missense Mutation (SNP) | VAF 46/87 reads (53%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- OTOL1 | c.407C>A p.P136Q | Missense Mutation (SNP) | VAF 130/285 reads (46%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- OXTR | c.503G>C p.S168T | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PARVG | c.668A>C p.K223T | Missense Mutation (SNP) | VAF 92/223 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- PATE1 | c.29C>T p.P10L | Missense Mutation (SNP) | VAF 15/144 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PCDH7 | c.3061G>T p.V1021L | Missense Mutation (SNP) | VAF 47/229 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCDHB7 | c.1184C>A p.P395Q | Missense Mutation (SNP) | VAF 56/126 reads (44%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.993); called by muse, mutect2
- PCDHGA5 | c.487G>T p.G163C | Missense Mutation (SNP) | VAF 69/146 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCNT | c.4269G>T p.K1423N | Missense Mutation (SNP) | VAF 160/324 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.654); called by muse, varscan2
- PGAP2 | c.107del p.F36Sfs*28 (on ENST00000463452 / NM_001346398.2; = p.F36Sfs*89 on NM_014489.4) | Frame Shift Del (DEL) | VAF 21/109 reads (19%) | called by mutect2, pindel, varscan2
- PGAP4 | c.657G>T p.Q219H | Missense Mutation (SNP) | VAF 74/182 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.385); called by muse, mutect2, varscan2
- PHLDB2 | c.2840C>A p.A947D (on ENST00000393925 / NM_001134439.2; = p.A904D on NM_145753.2) | Missense Mutation (SNP) | VAF 79/199 reads (40%) | SIFT tolerated (0.36); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- PKHD1L1 | c.659T>C p.M220T | Missense Mutation (SNP) | VAF 26/183 reads (14%) | SIFT tolerated (0.44); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PLCZ1 | c.824A>G p.D275G | Missense Mutation (SNP) | VAF 73/318 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- PLPPR5 | c.464G>A p.C155Y | Missense Mutation (SNP) | VAF 178/509 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLXNA3 | c.671T>A p.I224N | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- POLR3B | c.455C>A p.P152Q | Missense Mutation (SNP) | VAF 142/322 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- PPM1F | c.817G>T p.G273W | Missense Mutation (SNP) | VAF 81/181 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRAG1 | c.3851A>C p.Q1284P | Missense Mutation (SNP) | VAF 42/95 reads (44%) | SIFT tolerated (0.36); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PRLHR | c.237C>A p.C79* | Nonsense Mutation (SNP) | VAF 11/21 reads (52%) | called by muse, mutect2, varscan2
- PRR27 | c.179C>A p.P60H | Missense Mutation (SNP) | VAF 32/125 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- PRSS56 | c.1621G>T p.G541C | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PTPRT | c.3933C>A p.D1311E | Missense Mutation (SNP) | VAF 53/270 reads (20%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.669); called by muse, mutect2, varscan2
- PTPRT | c.2209C>A p.P737T | Missense Mutation (SNP) | VAF 44/202 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.71); called by muse, mutect2, varscan2
- PTPRT | c.897del p.V300Wfs*23 | Frame Shift Del (DEL) | VAF 13/63 reads (21%) | called by mutect2, pindel, varscan2
- RAD50 | c.2445G>T p.K815N | Missense Mutation (SNP) | VAF 50/242 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.022); called by muse, varscan2
- RAG1 | c.2938A>T p.R980W | Missense Mutation (SNP) | VAF 113/244 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- RAPGEF4 | c.816C>A p.N272K | Missense Mutation (SNP) | VAF 67/225 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- RBFOX3 | c.563C>A p.T188N | Missense Mutation (SNP) | VAF 71/462 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- RBM12 | c.1037G>T p.G346V | Missense Mutation (SNP) | VAF 90/253 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- RBM12 | c.1036G>T p.G346* | Nonsense Mutation (SNP) | VAF 90/257 reads (35%) | called by muse, mutect2, varscan2
- RGL3 | c.1226C>T p.P409L | Missense Mutation (SNP) | VAF 72/169 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RNF144B | c.269A>G p.E90G | Missense Mutation (SNP) | VAF 89/145 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RNF213 | c.1141G>T p.V381L | Missense Mutation (SNP) | VAF 148/586 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.414); called by muse, mutect2, varscan2
- RTTN | c.4484A>T p.K1495M | Missense Mutation (SNP) | VAF 37/126 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); called by muse, mutect2, varscan2
- RYR2 | c.683T>C p.L228P | Missense Mutation (SNP) | VAF 46/394 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- RYR2 | c.1352C>A p.S451Y | Missense Mutation (SNP) | VAF 12/171 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.607); called by muse, mutect2
- RYR2 | c.6176A>T p.Q2059L | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); called by muse, varscan2
- RYR2 | c.11564A>G p.Q3855R | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- RYR2 | c.12392C>A p.P4131H | Missense Mutation (SNP) | VAF 15/157 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- RYR2 | c.12998A>T p.N4333I | Missense Mutation (SNP) | VAF 26/36 reads (72%) | SIFT deleterious (0.03); PolyPhen benign (0.354); called by muse, mutect2, varscan2
- SEC31B | c.1316A>G p.E439G | Missense Mutation (SNP) | VAF 89/186 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SFI1 | c.1432G>T p.D478Y (on ENST00000400288 / NM_001007467.3; = p.D447Y on NM_014775.4) | Missense Mutation (SNP) | VAF 48/166 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SGCG | c.577A>T p.R193* | Nonsense Mutation (SNP) | VAF 99/446 reads (22%) | called by muse, mutect2, varscan2
- SLC13A5 | c.508C>A p.L170M | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- SLC17A8 | c.1381G>T p.G461* | Nonsense Mutation (SNP) | VAF 195/393 reads (50%) | called by muse, mutect2, varscan2
- SLC26A11 | c.1805C>T p.A602V | Missense Mutation (SNP) | VAF 188/264 reads (71%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SLC26A8 | c.1153T>C p.Y385H | Missense Mutation (SNP) | VAF 26/137 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC39A10 | c.2201A>G p.Y734C | Missense Mutation (SNP) | VAF 30/216 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); called by muse, varscan2
- SLC4A1 | c.1402del p.L468Cfs*17 | Frame Shift Del (DEL) | VAF 35/70 reads (50%) | called by mutect2, pindel, varscan2
- SLC6A17 | c.1152C>G p.S384R | Missense Mutation (SNP) | VAF 26/122 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.142); called by muse, varscan2
- SLC9A4 | c.1364C>T p.A455V | Missense Mutation (SNP) | VAF 20/252 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2
- SNCG | c.278G>T p.G93V | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.689); called by muse, mutect2, varscan2
- SPATA31A1 | c.1681A>G p.R561G | Missense Mutation (SNP) | VAF 30/137 reads (22%) | SIFT tolerated (0.42); PolyPhen benign (0.001); called by mutect2, varscan2
- SPATC1L | c.892A>C p.S298R (on ENST00000291672 / NM_001142854.2; = p.S144R on NM_032261.5) | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by mutect2, varscan2
- SPG11 | c.2263C>G p.Q755E | Missense Mutation (SNP) | VAF 116/267 reads (43%) | SIFT tolerated (0.44); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- SPTLC2 | c.1141T>G p.F381V | Missense Mutation (SNP) | VAF 49/312 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SRP72 | c.170A>T p.Q57L | Missense Mutation (SNP) | VAF 48/141 reads (34%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- STAB2 | c.2854G>C p.E952Q | Missense Mutation (SNP) | VAF 57/144 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- STIM2 | c.1645C>T p.H549Y | Missense Mutation (SNP) | VAF 58/383 reads (15%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.101); called by mutect2, varscan2
- STIMATE-MUSTN1 | c.1115G>T p.G372V | Missense Mutation (SNP) | VAF 140/320 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SUGCT | c.430G>T p.G144* | Nonsense Mutation (SNP) | VAF 84/303 reads (28%) | called by muse, mutect2, varscan2
- SVOP | c.1526C>A p.P509H | Missense Mutation (SNP) | VAF 113/240 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TAF1D | c.157G>C p.V53L | Missense Mutation (SNP) | VAF 60/178 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.273); called by muse, varscan2
- TAF1L | c.5203C>T p.P1735S | Missense Mutation (SNP) | VAF 48/306 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- TBC1D14 | c.1834G>T p.E612* | Nonsense Mutation (SNP) | VAF 109/349 reads (31%) | called by muse, mutect2, varscan2
- TBX4 | c.1459C>A p.P487T | Missense Mutation (SNP) | VAF 17/20 reads (85%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- TCF25 | c.308_311del p.E103Afs*44 | Frame Shift Del (DEL) | VAF 22/163 reads (13%) | called by mutect2, pindel, varscan2
- TECPR1 | c.3035G>T p.R1012L | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TECPR1 | c.118G>C p.A40P | Missense Mutation (SNP) | VAF 99/253 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TECTA | c.2092G>T p.V698L | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT tolerated (0.09); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- TEK | c.1000G>T p.G334* | Nonsense Mutation (SNP) | VAF 152/408 reads (37%) | called by muse, mutect2, varscan2
- TENM4 | c.5606G>A p.G1869E | Missense Mutation (SNP) | VAF 95/288 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TFCP2 | c.389A>T p.Q130L | Missense Mutation (SNP) | VAF 86/174 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); called by muse, mutect2, varscan2
- TGOLN2 | c.667A>T p.K223* | Nonsense Mutation (SNP) | VAF 96/273 reads (35%) | called by muse, mutect2, varscan2
- TMEM249 | c.561del p.K188Nfs*29 | Frame Shift Del (DEL) | VAF 16/96 reads (17%) | called by mutect2, pindel, varscan2
- TNXB | c.3079A>T p.I1027F | Missense Mutation (SNP) | VAF 26/45 reads (58%) | SIFT tolerated (0.53); PolyPhen benign (0.383); called by muse, mutect2, varscan2
- TP53BP1 | c.580C>G p.Q194E | Missense Mutation (SNP) | VAF 74/324 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRBJ2-2 | c.32G>T p.G11V | Missense Mutation (SNP) | VAF 139/340 reads (41%) | called by muse, mutect2, varscan2
- TRIM51 | c.171G>C p.K57N | Missense Mutation (SNP) | VAF 50/235 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- TRIM64B | c.1247C>G p.S416C | Missense Mutation (SNP) | VAF 75/627 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- TRIO | c.4018A>G p.I1340V | Missense Mutation (SNP) | VAF 74/176 reads (42%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- TRPC6 | c.598G>A p.E200K | Missense Mutation (SNP) | VAF 38/177 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.445); called by muse, mutect2, varscan2
- TSR1 | c.1683T>A p.H561Q | Missense Mutation (SNP) | VAF 93/234 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); called by muse, varscan2
- TTC21B | c.1622A>T p.K541I | Missense Mutation (SNP) | VAF 25/298 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); called by muse, mutect2
- TTC39B | c.1870del p.L624* | Frame Shift Del (DEL) | VAF 45/173 reads (26%) | called by mutect2, pindel, varscan2
- TTI1 | c.2882_2907del p.V961Gfs*26 | Frame Shift Del (DEL) | VAF 30/286 reads (10%) | called by mutect2, pindel
- TTLL13P | c.1859C>A p.P620H | Missense Mutation (SNP) | VAF 39/94 reads (41%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- TTN | c.92390A>G p.E30797G (on ENST00000591111; = p.E23373G on NM_003319.4) | Missense Mutation (SNP) | VAF 12/122 reads (10%) | PolyPhen probably damaging (0.997); called by muse, varscan2
- TTN | c.69856G>A p.V23286I (on ENST00000591111; = p.V15862I on NM_003319.4) | Missense Mutation (SNP) | VAF 12/55 reads (22%) | PolyPhen benign (0.082); called by muse, mutect2, varscan2
- UGGT2 | c.3728A>T p.E1243V | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UMOD | c.577T>A p.Y193N | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- UNC5D | c.2312A>C p.Q771P | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by mutect2, varscan2
- UNC80 | c.7630C>T p.L2544F | Missense Mutation (SNP) | VAF 77/254 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- VANGL2 | c.863C>A p.P288H | Missense Mutation (SNP) | VAF 65/548 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- VAX1 | c.497G>A p.R166H | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.828); called by muse, mutect2
- VWC2 | c.387C>A p.D129E | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.5); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- WASHC2A | c.2527G>A p.E843K | Missense Mutation (SNP) | VAF 28/141 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- WDFY3 | c.7594G>T p.E2532* | Nonsense Mutation (SNP) | VAF 51/121 reads (42%) | called by muse, mutect2, varscan2
- WDR88 | c.540G>A p.L180= | Splice Region (SNP) | VAF 40/111 reads (36%) | called by muse, mutect2, varscan2
- WNT10A | c.372C>A p.S124R | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- WNT8B | c.312C>G p.C104W | Missense Mutation (SNP) | VAF 51/279 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- WWC1 | c.2376G>T p.Q792H | Missense Mutation (SNP) | VAF 70/144 reads (49%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.592); called by muse, mutect2, varscan2
- XIRP2 | c.6750del p.K2251Nfs*8 (on ENST00000628543; = p.K2426Nfs*8 on NM_152381.6) | Frame Shift Del (DEL) | VAF 40/152 reads (26%) | called by pindel, varscan2
- XKR8 | c.691C>G p.L231V | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.052); called by muse, mutect2
- YES1 | c.1308C>G p.I436M | Missense Mutation (SNP) | VAF 66/243 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ZEB2 | c.445G>T p.A149S | Missense Mutation (SNP) | VAF 74/248 reads (30%) | SIFT tolerated (0.58); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- ZFHX4 | c.2008C>A p.P670T | Missense Mutation (SNP) | VAF 53/124 reads (43%) | SIFT tolerated (0.29); PolyPhen benign (0.359); called by muse, mutect2, varscan2
- ZFHX4 | c.8570C>A p.T2857K | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- ZNF133 | c.1297_1298del p.T433Wfs*15 (on ENST00000316358 / NM_001352454.2; = p.T432Wfs*15 on NM_003434.7 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 18/49 reads (37%) | called by pindel, varscan2
- ZNF33B | c.56T>A p.V19E | Missense Mutation (SNP) | VAF 121/311 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF462 | c.5687A>T p.H1896L | Missense Mutation (SNP) | VAF 36/196 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ZNF471 | c.146G>T p.S49I | Missense Mutation (SNP) | VAF 83/158 reads (53%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.522); called by muse, mutect2, varscan2
- ZNF728 | c.680C>A p.P227H | Missense Mutation (SNP) | VAF 94/227 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ABCC11 | c.2754G>C p.R918= | Silent (SNP) | VAF 87/211 reads (41%) | called by muse, mutect2, varscan2
- ADAMTSL3 | c.372T>C p.P124= | Silent (SNP) | VAF 28/68 reads (41%) | called by muse, varscan2
- ADRA2C | c.1363C>A p.R455= | Silent (SNP) | VAF 7/55 reads (13%) | called by mutect2, varscan2
- AGTPBP1 | c.1500A>G p.E500= (on ENST00000357081 / NM_001330701.2; = p.E460= on NM_015239.2) | Silent (SNP) | VAF 13/85 reads (15%) | called by muse, mutect2, varscan2
- ALG8 | c.15A>C p.T5= | Silent (SNP) | VAF 41/234 reads (18%) | called by muse, mutect2, varscan2
- ANGPT1 | c.240C>A p.S80= | Silent (SNP) | VAF 86/235 reads (37%) | called by muse, mutect2, varscan2
- ANGPT2 | c.1248C>A p.I416= | Silent (SNP) | VAF 64/127 reads (50%) | called by muse, mutect2, varscan2
- ANKRD33B | c.861G>T p.V287= | Silent (SNP) | VAF 61/107 reads (57%) | called by muse, mutect2, varscan2
- ANKRD35 | c.669G>T p.L223= | Silent (SNP) | VAF 87/192 reads (45%) | called by muse, mutect2, varscan2
- ARHGEF1 | c.807G>T p.L269= | Silent (SNP) | VAF 8/14 reads (57%) | called by muse, mutect2, varscan2
- ATAD3C | c.384C>A p.V128= | Silent (SNP) | VAF 39/168 reads (23%) | called by muse, mutect2, varscan2
- C9orf72 | c.912C>T p.P304= | Silent (SNP) | VAF 55/158 reads (35%) | catalogued as COSV66155258; called by muse, mutect2, varscan2
- CARD11 | c.501G>A p.T167= | Silent (SNP) | VAF 80/531 reads (15%) | catalogued as rs757881829, COSV62716578; called by muse, mutect2, varscan2
- CATSPERB | c.2976T>C p.N992= | Silent (SNP) | VAF 32/121 reads (26%) | called by muse, mutect2, varscan2
- CD1E | c.816C>A p.T272= | Silent (SNP) | VAF 47/117 reads (40%) | catalogued as COSV63770714; called by muse, mutect2, varscan2
- CD6 | c.213G>A p.G71= | Silent (SNP) | VAF 10/45 reads (22%) | called by muse, mutect2, varscan2
- CHRNA7 | c.720C>G p.P240= | Silent (SNP) | VAF 50/417 reads (12%) | called by muse, mutect2, varscan2
- CLDN8 | c.210G>C p.L70= | Silent (SNP) | VAF 11/72 reads (15%) | called by muse, mutect2, varscan2
- COPA | c.1899C>G p.G633= | Silent (SNP) | VAF 120/315 reads (38%) | called by muse, mutect2, varscan2
- CPS1 | c.4098C>A p.I1366= | Silent (SNP) | VAF 109/423 reads (26%) | called by muse, mutect2, varscan2
- CRACD | c.2049G>T p.P683= | Silent (SNP) | VAF 64/180 reads (36%) | catalogued as rs183317269; called by muse, mutect2, varscan2
- CRB2 | c.1212C>A p.T404= | Silent (SNP) | VAF 87/157 reads (55%) | called by muse, mutect2, varscan2
- CREBBP | c.6135G>A p.Q2045= | Silent (SNP) | VAF 82/140 reads (59%) | called by muse, mutect2, varscan2
- CRISP2 | c.213C>A p.A71= | Silent (SNP) | VAF 142/275 reads (52%) | catalogued as COSV100188851; called by muse, mutect2, varscan2
- CTNNA3 | c.2241C>A p.V747= | Silent (SNP) | VAF 72/161 reads (45%) | catalogued as COSV65523022; called by muse, mutect2, varscan2
- CYP2D7 | c.756T>C p.D252= | Silent (SNP) | VAF 64/413 reads (15%) | called by muse, mutect2, varscan2
- DDI1 | c.312G>A p.T104= | Silent (SNP) | VAF 15/88 reads (17%) | catalogued as rs776400594, COSV56376753; called by muse, mutect2, varscan2
- DDX18 | c.873A>G p.R291= | Silent (SNP) | VAF 66/433 reads (15%) | called by muse, mutect2, varscan2
- DNAH6 | c.4728T>A p.P1576= | Silent (SNP) | VAF 87/193 reads (45%) | called by muse, mutect2, varscan2
- DPYS | c.777G>T p.A259= | Silent (SNP) | VAF 71/385 reads (18%) | catalogued as COSV60909475; called by muse, mutect2, varscan2
- EBNA1BP2 | c.216G>T p.V72= | Silent (SNP) | VAF 48/213 reads (23%) | called by muse, mutect2, varscan2
- ENTPD2 | c.687C>T p.Y229= | Silent (SNP) | VAF 63/281 reads (22%) | catalogued as rs201122803; called by muse, mutect2, varscan2
- EVX1 | c.873C>T p.S291= | Silent (SNP) | VAF 11/91 reads (12%) | catalogued as rs770776117; called by muse, mutect2, varscan2
- FAM184B | c.366G>T p.S122= | Silent (SNP) | VAF 13/32 reads (41%) | called by muse, mutect2, varscan2
- FFAR1 | c.180C>G p.P60= | Silent (SNP) | VAF 18/50 reads (36%) | called by muse, mutect2, varscan2
- FGF23 | c.492C>A p.I164= | Silent (SNP) | VAF 32/131 reads (24%) | called by muse, mutect2, varscan2
- FGF6 | c.108G>T p.V36= | Silent (SNP) | VAF 36/101 reads (36%) | catalogued as rs377040252; called by muse, mutect2, varscan2
- FGR | c.219T>C p.G73= | Silent (SNP) | VAF 50/246 reads (20%) | called by muse, mutect2, varscan2
- FIBIN | c.288C>A p.R96= | Silent (SNP) | VAF 3/16 reads (19%) | called by muse, mutect2
- FRAS1 | c.8322A>T p.A2774= | Silent (SNP) | VAF 10/90 reads (11%) | called by muse, mutect2, varscan2
- FRG2 | c.711T>A p.A237= | Silent (SNP) | VAF 55/336 reads (16%) | called by muse, varscan2
- GKN1 | c.474G>A p.L158= | Silent (SNP) | VAF 59/221 reads (27%) | catalogued as rs191187603; called by muse, mutect2, varscan2
- GLI1 | c.2310C>T p.A770= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as COSV99953733; called by muse, mutect2, varscan2
- GLIS1 | c.693C>T p.C231= | Silent (SNP) | VAF 41/157 reads (26%) | catalogued as rs1348997780; called by muse, mutect2, varscan2
- GLP1R | c.624C>A p.A208= | Silent (SNP) | VAF 76/150 reads (51%) | catalogued as rs533070567; called by muse, varscan2
- GPR158 | c.69C>A p.G23= | Silent (SNP) | VAF 30/65 reads (46%) | called by muse, mutect2, varscan2
- GRIN2A | c.4224G>A p.T1408= | Silent (SNP) | VAF 76/301 reads (25%) | catalogued as rs773175225; called by muse, mutect2, varscan2
- IGKV2-30 | c.114G>T p.P38= | Silent (SNP) | VAF 59/315 reads (19%) | catalogued as rs758912589; called by muse, mutect2, varscan2
- KCNAB2 | c.1008A>T p.A336= | Silent (SNP) | VAF 23/129 reads (18%) | called by muse, mutect2, varscan2
- KCNH5 | c.1137C>G p.V379= | Silent (SNP) | VAF 82/387 reads (21%) | called by muse, mutect2, varscan2
- KLHL40 | c.804G>A p.L268= | Silent (SNP) | VAF 27/137 reads (20%) | called by muse, mutect2, varscan2
- LBP | c.1374C>T p.L458= | Silent (SNP) | VAF 39/262 reads (15%) | catalogued as rs1329406612; called by muse, mutect2, varscan2
- LCP2 | c.1380C>A p.V460= | Silent (SNP) | VAF 85/204 reads (42%) | called by muse, mutect2, varscan2
- LPCAT2 | c.114G>T p.P38= | Silent (SNP) | VAF 12/27 reads (44%) | catalogued as rs767604615; called by muse, mutect2, varscan2
- LRRC8B | c.252G>T p.G84= | Silent (SNP) | VAF 53/256 reads (21%) | catalogued as rs1208416988, COSV58377209; called by muse, mutect2, varscan2
- LZTR1 | c.1767G>T p.L589= | Silent (SNP) | VAF 53/127 reads (42%) | called by muse, mutect2, varscan2
- LZTS1 | c.504T>A p.S168= | Silent (SNP) | VAF 28/63 reads (44%) | called by muse, mutect2, varscan2
- MACF1 | c.3708A>G p.P1236= | Silent (SNP) | VAF 58/270 reads (21%) | catalogued as rs773953982; called by muse, mutect2, varscan2
- MAGEL2 | c.2031G>T p.V677= | Silent (SNP) | VAF 4/10 reads (40%) | called by muse, mutect2
- MCC | c.861G>T p.V287= | Silent (SNP) | VAF 18/53 reads (34%) | called by muse, mutect2
- MED16 | c.66G>A p.E22= | Silent (SNP) | VAF 59/148 reads (40%) | called by muse, mutect2, varscan2
- MEP1A | c.795T>C p.L265= | Silent (SNP) | VAF 16/75 reads (21%) | called by muse, varscan2
- MOV10L1 | c.1284C>A p.L428= | Silent (SNP) | VAF 46/85 reads (54%) | called by muse, mutect2, varscan2
- MYO5B | c.4269C>G p.L1423= | Silent (SNP) | VAF 168/454 reads (37%) | catalogued as rs1236120415; called by muse, mutect2, varscan2
- NFRKB | c.1284A>T p.L428= (on ENST00000446488 / NM_001143835.2; = p.L453= on NM_006165.3) | Silent (SNP) | VAF 55/243 reads (23%) | called by muse, mutect2, varscan2
- NKIRAS2 | c.474G>T p.L158= | Silent (SNP) | VAF 108/228 reads (47%) | called by muse, mutect2, varscan2
- NLRP12 | c.858C>A p.P286= | Silent (SNP) | VAF 90/148 reads (61%) | called by mutect2, varscan2
- NOC2L | c.426G>T p.G142= | Silent (SNP) | VAF 42/169 reads (25%) | called by muse, mutect2, varscan2
- NOL4L | c.676C>A p.R226= | Silent (SNP) | VAF 27/128 reads (21%) | called by muse, mutect2, varscan2
- NOP2 | c.807G>T p.R269= (on ENST00000322166 / NM_001258308.2; = p.R265= on NM_006170.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 58/126 reads (46%) | called by muse, mutect2, varscan2
- NTRK1 | c.2136C>T p.S712= | Silent (SNP) | VAF 37/324 reads (11%) | catalogued as COSV62325999; called by muse, mutect2, varscan2
- NUTM1 | c.2316T>C p.P772= | Silent (SNP) | VAF 17/30 reads (57%) | called by muse, mutect2, varscan2
- OR10Q1 | c.480C>A p.S160= | Silent (SNP) | VAF 112/280 reads (40%) | called by muse, mutect2, varscan2
- OR10R2 | c.123T>A p.G41= | Silent (SNP) | VAF 145/592 reads (24%) | called by muse, mutect2, varscan2
- OR2W3 | c.612G>T p.V204= | Silent (SNP) | VAF 50/202 reads (25%) | called by muse, varscan2
- OR56A1 | c.915A>G p.G305= | Silent (SNP) | VAF 9/39 reads (23%) | called by muse, mutect2, varscan2
- OTOGL | c.1653G>C p.V551= (on ENST00000547103; = p.V542= on NM_173591.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 72/180 reads (40%) | called by muse, mutect2, varscan2
- PCDH10 | c.102G>T p.V34= | Silent (SNP) | VAF 41/101 reads (41%) | called by muse, mutect2, varscan2
- PCDH10 | c.306C>A p.P102= | Silent (SNP) | VAF 117/301 reads (39%) | called by muse, mutect2, varscan2
- PCDHA11 | c.1648C>T p.L550= | Silent (SNP) | VAF 61/329 reads (19%) | called by muse, varscan2
- PCDHA13 | c.1650G>T p.T550= | Silent (SNP) | VAF 144/295 reads (49%) | catalogued as COSV56476677; called by muse, mutect2, varscan2
- PCDHA2 | c.1788A>T p.A596= | Silent (SNP) | VAF 101/227 reads (44%) | catalogued as rs1359473362; called by muse, mutect2, varscan2
- PCDHB11 | c.1353C>T p.F451= | Silent (SNP) | VAF 170/380 reads (45%) | called by muse, mutect2, varscan2
- PDCL3 | c.345C>T p.V115= | Silent (SNP) | VAF 31/114 reads (27%) | called by muse, mutect2, varscan2
- PGAP4 | c.1164C>A p.I388= | Silent (SNP) | VAF 21/139 reads (15%) | catalogued as COSV66387407; called by muse, mutect2, varscan2
- PHF2 | c.1836C>A p.S612= | Silent (SNP) | VAF 41/92 reads (45%) | called by muse, mutect2, varscan2
- PHLDB1 | c.1128C>T p.T376= | Silent (SNP) | VAF 60/153 reads (39%) | called by muse, mutect2, varscan2
- PLCB1 | c.2091G>T p.V697= | Silent (SNP) | VAF 51/113 reads (45%) | called by muse, mutect2, varscan2
- PLXNB3 | c.936G>A p.A312= | Silent (SNP) | VAF 19/36 reads (53%) | catalogued as rs782022295; called by muse, mutect2, varscan2
- PRSS41 | c.924C>A p.I308= | Silent (SNP) | VAF 82/180 reads (46%) | called by muse, mutect2, varscan2
- PSMC5 | c.444T>C p.Y148= | Silent (SNP) | VAF 99/656 reads (15%) | catalogued as rs1245420132; called by muse, mutect2, varscan2
- PURB | c.66G>T p.A22= | Silent (SNP) | VAF 11/73 reads (15%) | catalogued as rs772321227; called by muse, mutect2, varscan2
- RABGAP1 | c.1011T>G p.T337= | Silent (SNP) | VAF 48/107 reads (45%) | called by muse, mutect2, varscan2
- RAPGEFL1 | c.529C>T p.L177= | Silent (SNP) | VAF 61/112 reads (54%) | called by muse, mutect2, varscan2
- RASAL3 | c.1344G>T p.G448= | Silent (SNP) | VAF 18/41 reads (44%) | called by muse, varscan2
- RASGRP2 | c.1048C>T p.L350= | Silent (SNP) | VAF 63/175 reads (36%) | called by muse, mutect2, varscan2
- RBM20 | c.2445T>A p.P815= | Silent (SNP) | VAF 8/14 reads (57%) | called by muse, varscan2
- RYR3 | c.8505C>A p.A2835= (on ENST00000389232; = p.A2836= on NM_001036.6) | Silent (SNP) | VAF 49/108 reads (45%) | catalogued as rs202071959, COSV66781872; called by muse, mutect2, varscan2
- SCG3 | c.585G>A p.E195= | Silent (SNP) | VAF 74/161 reads (46%) | catalogued as rs1253637680, COSV55021931; called by muse, mutect2, varscan2
- SCN11A | c.4923C>T p.I1641= | Silent (SNP) | VAF 23/156 reads (15%) | catalogued as COSV56574592; called by muse, mutect2, varscan2
- SIGLEC8 | c.990T>A p.A330= | Silent (SNP) | VAF 84/230 reads (37%) | called by muse, mutect2, varscan2
- SLC13A5 | c.276C>T p.G92= | Silent (SNP) | VAF 35/175 reads (20%) | catalogued as rs771703938, COSV99546251; called by muse, mutect2, varscan2
- SLIT2 | c.825C>T p.A275= | Silent (SNP) | VAF 37/235 reads (16%) | catalogued as rs557268494, COSV56580284; called by muse, mutect2, varscan2
- SMC6 | c.537C>T p.N179= | Silent (SNP) | VAF 79/166 reads (48%) | called by muse, mutect2, varscan2
- SMPD4 | c.1932C>T p.D644= (on ENST00000409031 / NM_017951.4; = p.D615= on NM_017751.4) | Silent (SNP) | VAF 54/397 reads (14%) | catalogued as rs781166037; called by muse, mutect2, varscan2
- SOX4 | c.426C>T p.S142= | Silent (SNP) | VAF 11/32 reads (34%) | called by mutect2, varscan2
- SPAG1 | c.1020T>A p.V340= | Silent (SNP) | VAF 45/205 reads (22%) | called by muse, mutect2, varscan2
- SPPL2B | c.1452G>A p.T484= | Silent (SNP) | VAF 11/196 reads (6%) | catalogued as rs1449600937; called by muse, mutect2
- ST6GAL2 | c.144C>A p.T48= | Silent (SNP) | VAF 40/156 reads (26%) | called by muse, mutect2, varscan2
- SULF1 | c.480T>A p.L160= | Silent (SNP) | VAF 66/237 reads (28%) | called by muse, mutect2, varscan2
- TGFBR3L | c.565C>T p.L189= | Silent (SNP) | VAF 10/38 reads (26%) | called by muse, mutect2, varscan2
- TGM7 | c.1419T>G p.S473= | Silent (SNP) | VAF 55/122 reads (45%) | called by muse, mutect2, varscan2
- THNSL2 | c.345G>A p.L115= | Silent (SNP) | VAF 77/258 reads (30%) | called by muse, varscan2
- THOC3 | c.12C>T p.P4= | Silent (SNP) | VAF 27/163 reads (17%) | called by muse, mutect2, varscan2
- TPO | c.2058G>T p.L686= | Silent (SNP) | VAF 125/238 reads (53%) | called by muse, mutect2, varscan2
- TRAPPC9 | c.2121A>G p.A707= | Silent (SNP) | VAF 43/232 reads (19%) | catalogued as rs149959014; called by muse, varscan2
- TRIM64C | c.1089A>G p.T363= | Silent (SNP) | VAF 102/218 reads (47%) | called by muse, mutect2, varscan2
- TRPM1 | c.2457G>A p.K819= | Silent (SNP) | VAF 89/468 reads (19%) | called by muse, mutect2, varscan2
- TRPS1 | c.2760T>C p.C920= (on ENST00000220888 / NM_001330599.2; = p.C933= on NM_014112.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 83/496 reads (17%) | catalogued as CM095513; called by muse, mutect2, varscan2
- TYR | c.1155C>T p.I385= | Silent (SNP) | VAF 143/395 reads (36%) | called by muse, mutect2, varscan2
- UBE2M | c.399G>A p.Q133= | Silent (SNP) | VAF 51/124 reads (41%) | catalogued as COSV99448490; called by muse, mutect2, varscan2
- UNC80 | c.4341C>T p.A1447= | Silent (SNP) | VAF 117/472 reads (25%) | catalogued as rs533991987, COSV55891182, COSV55903725; called by muse, mutect2, varscan2
- UNK | c.2211G>A p.A737= | Silent (SNP) | VAF 9/71 reads (13%) | catalogued as rs372625164; called by muse, mutect2, varscan2
- USP11 | c.1785G>T p.R595= (on ENST00000218348; = p.R552= on NM_001371072.1) | Silent (SNP) | VAF 55/145 reads (38%) | called by muse, mutect2, varscan2
- VANGL2 | c.9C>A p.T3= | Silent (SNP) | VAF 60/361 reads (17%) | called by muse, mutect2, varscan2
- VCAM1 | c.474C>A p.L158= | Silent (SNP) | VAF 56/358 reads (16%) | catalogued as COSV54120077; called by muse, mutect2, varscan2
- WNT2 | c.111C>T p.S37= | Silent (SNP) | VAF 90/204 reads (44%) | called by muse, mutect2, varscan2
- ZBTB16 | c.537C>T p.P179= | Silent (SNP) | VAF 20/102 reads (20%) | catalogued as rs368971745; called by muse, mutect2, varscan2
- ZNF414 | c.846C>T p.S282= | Silent (SNP) | VAF 5/10 reads (50%) | called by muse, varscan2
- ZNF98 | c.879C>G p.P293= | Silent (SNP) | VAF 21/34 reads (62%) | called by mutect2, varscan2
- ABCB11 | c.-19G>T | 5'UTR (SNP) | VAF 35/121 reads (29%) | called by muse, mutect2, varscan2
- AC092718.9 | chr16:81148324 A>T | 5'Flank (SNP) | VAF 78/178 reads (44%) | called by muse, mutect2, varscan2
- AC125421.2 | chr17:73828456 C>A | 3'Flank (SNP) | VAF 11/47 reads (23%) | called by muse, mutect2, varscan2
- AC134312.1 | n.1257C>T | RNA (SNP) | VAF 13/55 reads (24%) | catalogued as rs752372861; called by muse, mutect2, varscan2
- ADCY4 | c.357+9G>A | Intron (SNP) | VAF 3/12 reads (25%) | catalogued as rs780040632; called by muse, mutect2
- ADIG | c.125-521G>T | Intron (SNP) | VAF 18/124 reads (15%) | called by muse, mutect2, varscan2
- AHSG | c.-53G>T | 5'UTR (SNP) | VAF 127/277 reads (46%) | catalogued as rs559479308; called by muse, mutect2, varscan2
- ANKRD26P1 | n.486C>T | RNA (SNP) | VAF 35/77 reads (45%) | called by muse, mutect2, varscan2
- ARHGEF40 | c.-54C>A | 5'UTR (SNP) | VAF 21/32 reads (66%) | called by muse, mutect2, varscan2
- ATP2A3 | chr17:3924808 A>G | 3'Flank (SNP) | VAF 19/116 reads (16%) | called by muse, mutect2, varscan2
- C14orf132 | chr14:96090863 C>T | 3'Flank (SNP) | VAF 60/299 reads (20%) | called by muse, mutect2, varscan2
- C3 | c.4172+10T>G | Intron (SNP) | VAF 79/347 reads (23%) | called by muse, mutect2, varscan2
- CA14 | c.76+126A>G | Intron (SNP) | VAF 91/191 reads (48%) | called by muse, mutect2, varscan2
- CAMK1G | c.-4_-2delinsA | 5'UTR (DEL) | VAF 30/70 reads (43%) | called by pindel, varscan2*
- CARD9 | c.1270-16T>A | Intron (SNP) | VAF 40/160 reads (25%) | called by muse, mutect2, varscan2
- CLRN1 | c.*64T>C | 3'UTR (SNP) | VAF 20/93 reads (22%) | called by muse, mutect2, varscan2
- COBL | c.1096+11852C>A | Intron (SNP) | VAF 42/101 reads (42%) | catalogued as rs1308487182; called by muse, mutect2, varscan2
- CTBP2 | c.58+12776del | Intron (DEL) | VAF 21/87 reads (24%) | called by mutect2, pindel, varscan2
- CUX1 | chr7:101816050 C>A | 5'Flank (SNP) | VAF 158/425 reads (37%) | called by muse, mutect2, varscan2
- CYB5RL | chr1:54171231 C>G | 3'Flank (SNP) | VAF 58/274 reads (21%) | called by muse, mutect2, varscan2
- DGLUCY | c.257+153C>T | Intron (SNP) | VAF 61/265 reads (23%) | called by muse, mutect2, varscan2
- EEF1B2 | c.398-161A>G | Intron (SNP) | VAF 31/195 reads (16%) | catalogued as rs774570428; called by muse, mutect2, varscan2
- EMBP1 | n.1135G>A | RNA (SNP) | VAF 20/145 reads (14%) | called by muse, mutect2, varscan2
- FAM230J | n.812G>T | RNA (SNP) | VAF 33/60 reads (55%) | catalogued as rs779015778; called by muse, mutect2, varscan2
- FBXO24 | c.39+78A>T | Intron (SNP) | VAF 40/233 reads (17%) | catalogued as rs1273753933; called by muse, mutect2, varscan2
- GALNT14 | c.129+12750C>A | Intron (SNP) | VAF 146/323 reads (45%) | called by muse, mutect2, varscan2
- GCSAML | c.-56-10402C>A | Intron (SNP) | VAF 188/291 reads (65%) | called by muse, mutect2, varscan2
- GDAP1L1 | c.760+80T>C | Intron (SNP) | VAF 9/126 reads (7%) | catalogued as COSV100697446; called by muse, mutect2
- GPSM1 | c.1207+12G>T | Intron (SNP) | VAF 20/50 reads (40%) | called by muse, mutect2, varscan2
- H2BC18 | c.378-9409G>T | Intron (SNP) | VAF 31/53 reads (58%) | catalogued as rs1204798706; called by muse, mutect2, varscan2
- H2BP2 | chr1:143876096 G>A | 3'Flank (SNP) | VAF 70/932 reads (8%) | catalogued as rs1381525689; called by muse, mutect2
- H2BP2 | n.1062-382G>T | Intron (SNP) | VAF 70/437 reads (16%) | called by muse, mutect2, varscan2
- HLX | c.773-12G>A | Intron (SNP) | VAF 35/156 reads (22%) | called by muse, mutect2, varscan2
- IGKV3-20 | c.-11C>A | 5'UTR (SNP) | VAF 41/197 reads (21%) | called by muse, mutect2, varscan2
- IL1RAP | chr3:190656102 C>T | 3'Flank (SNP) | VAF 158/321 reads (49%) | catalogued as COSV50760336; called by muse, mutect2, varscan2
- IRX1 | c.*6G>T | 3'UTR (SNP) | VAF 90/311 reads (29%) | called by muse, mutect2, varscan2
- KCND2 | c.1279-666C>A | Intron (SNP) | VAF 110/366 reads (30%) | called by muse, mutect2, varscan2
- KIF17 | c.231+26G>C | Intron (SNP) | VAF 7/40 reads (18%) | called by muse, mutect2
- KLK12 | c.*12C>A | 3'UTR (SNP) | VAF 189/364 reads (52%) | called by muse, mutect2, varscan2
- KNTC1 | c.6031-890A>T | Intron (SNP) | VAF 67/162 reads (41%) | called by muse, mutect2, varscan2
- LDLRAD2 | c.*1856C>A | 3'UTR (SNP) | VAF 25/98 reads (26%) | called by muse, mutect2, varscan2
- LINC00967 | n.932C>T | RNA (SNP) | VAF 17/99 reads (17%) | catalogued as rs912764617; called by muse, mutect2
- LINC01804 | n.312T>G | RNA (SNP) | VAF 22/176 reads (13%) | called by muse, mutect2, varscan2
- LINC02169 | n.654_656dup | RNA (INS) | VAF 18/76 reads (24%) | called by pindel, varscan2
- LINC02253 | n.488-13463T>C | Intron (SNP) | VAF 83/153 reads (54%) | called by muse, varscan2
- LRRC63 | chr13:46270509 G>T | 3'Flank (SNP) | VAF 48/120 reads (40%) | called by muse, mutect2, varscan2
- NRSN1 | c.190-4601C>T | Intron (SNP) | VAF 13/20 reads (65%) | called by muse, varscan2
- ODF2L | chr1:86348892 G>A | 3'Flank (SNP) | VAF 40/139 reads (29%) | catalogued as rs1332099154, COSV99644037; called by muse, mutect2, varscan2
- OR2L1P | n.382A>G | RNA (SNP) | VAF 230/378 reads (61%) | called by muse, mutect2, varscan2
- OR9Q1 | c.-15+53306T>C | Intron (SNP) | VAF 41/263 reads (16%) | called by muse, mutect2, varscan2
- PCSK9 | c.524-1144C>T | Intron (SNP) | VAF 46/188 reads (24%) | catalogued as rs943276990; called by muse, mutect2, varscan2
- PFKL | c.86-2390A>T | Intron (SNP) | VAF 38/147 reads (26%) | catalogued as rs1457730476; called by muse, mutect2, varscan2
- PRKAG3 | c.-11G>C | 5'UTR (SNP) | VAF 42/164 reads (26%) | catalogued as rs750503932; called by muse, mutect2, varscan2
- PSMA6 | c.172-10dup | Intron (INS) | VAF 60/123 reads (49%) | called by mutect2, pindel, varscan2
- PSMG3-AS1 | n.3693C>G | RNA (SNP) | VAF 47/305 reads (15%) | called by muse, mutect2, varscan2
- RBFOX1 | c.931-5201C>A | Intron (SNP) | VAF 30/166 reads (18%) | catalogued as COSV100302666; called by muse, varscan2
- RIIAD1 | c.-1104C>A | 5'UTR (SNP) | VAF 25/164 reads (15%) | called by muse, mutect2, varscan2
- RSRC1 | c.912+28A>T | Intron (SNP) | VAF 27/42 reads (64%) | catalogued as COSV55835042; called by muse, mutect2, varscan2
- SLC8A3 | c.1785-2978C>A | Intron (SNP) | VAF 46/87 reads (53%) | called by muse, mutect2, varscan2
- SLIT2 | c.*1412C>G | 3'UTR (SNP) | VAF 53/167 reads (32%) | called by muse, mutect2, varscan2
- SMIM3 | c.-272G>A | 5'UTR (SNP) | VAF 15/28 reads (54%) | called by muse, mutect2, varscan2
- ST7 | c.151+2746C>A | Intron (SNP) | VAF 28/76 reads (37%) | called by muse, varscan2
- STXBP2 | c.246+458C>T | Intron (SNP) | VAF 91/469 reads (19%) | catalogued as rs535157503; called by muse, varscan2
- SULF1 | c.*684C>A | 3'UTR (SNP) | VAF 18/114 reads (16%) | called by muse, mutect2, varscan2
- TAAR3P | n.937A>C | RNA (SNP) | VAF 63/150 reads (42%) | called by muse, mutect2, varscan2
- TBX2 | c.1051+142C>A | Intron (SNP) | VAF 215/306 reads (70%) | called by muse, mutect2, varscan2
- TBX2 | c.1051+143C>A | Intron (SNP) | VAF 213/304 reads (70%) | called by muse, mutect2, varscan2
- TMEM143 | chr19:48363958 ins C | 5'Flank (INS) | VAF 8/28 reads (29%) | called by mutect2, pindel
- TMPRSS11F | c.1015+1766G>C | Intron (SNP) | VAF 41/302 reads (14%) | called by muse, mutect2, varscan2
- TPRXL | n.1011G>C | RNA (SNP) | VAF 100/214 reads (47%) | called by muse, mutect2, varscan2
- TRBV25OR9-2 | n.132T>C | RNA (SNP) | VAF 23/143 reads (16%) | catalogued as rs1278545151; called by muse, mutect2, varscan2
- TTC21A | c.268+20A>T | Intron (SNP) | VAF 129/314 reads (41%) | called by muse, mutect2, varscan2
- TTLL2 | c.47+2798A>T | Intron (SNP) | VAF 117/230 reads (51%) | called by muse, mutect2, varscan2
- TTN | c.10360+3493A>T | Intron (SNP) | VAF 15/86 reads (17%) | catalogued as rs779286432; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UMODL1 | c.1900-28A>T | Intron (SNP) | VAF 69/140 reads (49%) | called by muse, mutect2, varscan2
- WASF4P | n.1289C>T | RNA (SNP) | VAF 24/40 reads (60%) | catalogued as rs782548534; called by muse, mutect2, varscan2
- WDR49 | c.-65-16088G>T | Intron (SNP) | VAF 67/129 reads (52%) | called by muse, mutect2, varscan2
- WT1 | chr11:32439243 G>T | 5'Flank (SNP) | VAF 29/84 reads (35%) | catalogued as rs373581806; called by muse, mutect2, varscan2
- WT1 | chr11:32439244 G>T | 5'Flank (SNP) | VAF 28/82 reads (34%) | called by muse, mutect2, varscan2
- XIRP2 | c.*411C>A | 3'UTR (SNP) | VAF 53/148 reads (36%) | catalogued as COSV54682679; called by muse, mutect2, varscan2
- ZBTB37 | c.1023+12T>C | Intron (SNP) | VAF 149/262 reads (57%) | called by muse, mutect2, varscan2
- ZFP57 | c.-11C>A | 5'UTR (SNP) | VAF 186/342 reads (54%) | called by muse, mutect2, varscan2
- ZFYVE28 | c.701+4717G>T | Intron (SNP) | VAF 36/113 reads (32%) | called by muse, mutect2, varscan2
- ZNF849P | n.109T>A | RNA (SNP) | VAF 21/104 reads (20%) | called by muse, mutect2
- ZNF849P | n.111T>G | RNA (SNP) | VAF 21/105 reads (20%) | catalogued as rs757196619; called by muse, mutect2
